CCDI case PBCPCR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Vagina.
https://portal.gdc.cancer.gov/cases/4d8787a7-3834-412c-bbd2-6b02178161dc

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Vagina, NOS; Age at diagnosis: 11.4 years (4,149 days).

Biospecimens (3 samples)
- Sample 0DWLYS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWM0C: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWM1E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
